Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4RU, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4RU-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

*Carcinosarcoma / Mixed
Mullerian Tumor, malignant
8950/3
Site Endometrium (54.1)
JW 4/2/13*

Specimens Submitted:

- 1: SP: Left para-aortic lymph nodes (fs))
- 2: SP: Right para-aortic lymph nodes (fs))
- 3: SP: Uterus, cervix, tubes and ovaries bilateral
- 4: SP: High right para-aortic lymph nodes
- 5: SP: Left side wall tumor
- 6: SP: Right external iliac lymph nodes
- 7: SP: Omental biopsy

DIAGNOSIS:

- 1) LYMPH NODES, LEFT PARA-AORTIC, EXCISION:
- METASTATIC TUMOR IN FOUR OF FIVE LYMPH NODES (4/5).
- 2) LYMPH NODES, RIGHT PARA-AORTIC, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 3) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES, TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- MALIGNANT MIXED MULLERIAN TUMOR OF ENDOMETRIUM (SEE NOTE).
- THE TUMOR INVADES TO <= HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 1MM
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 14 MM
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- VASCULAR INVASION IS PRESENT.
- TUMOR IS PRESENT IN THE PARA-CERVICAL SOFT TISSUE.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ATROPHY.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ADENOMYOSIS.
- THE RIGHT OVARY SHOWS METASTATIC TUMOR.
- THE LEFT OVARY SHOWS METASTATIC TUMOR.
- DETACHED FRAGMENT OF TUMOR IS PRESENT IN THE LEFT FALLOPIAN TUBE.
- THE RIGHT FALLOPIAN TUBE IS UNREMARKABLE.

NOTE: IMMUNOHISTOCHEMICAL STAINS ARE BEING PERFORMED TO RULE OUT THE PRESENCE OF HETEROLOGUS ELEMENTS. THE RESULTS WILL BE REPORTED IN AN

** Continued on next page **

[page 2 of 3]
ADDENDUM.

- 4) LYMPH NODES, HIGH RIGHT PARA-AORTIC, EXCISION:
- FIBROADIPOSE TISSUE AND NERVE, NEGATIVE FOR METASTATIC TUMOR.
- NO LYMPH NODE IS IDENTIFIED.
- 5) SOFT TISSUE, "LEFT SIDE WALL TUMOR", EXCISION:
- METASTATIC TUMOR.
- 6) LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) OMENTUM, BIOPSY:
- OMENTUM, NEGATIVE FOR METASTATIC TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 3 of 3]
This image shows a blank, aged, cream-colored page, likely an endpaper or flyleaf of a book. The paper has a slightly textured appearance with some minor creases and discoloration, characteristic of old paper. A small, dark, rectangular object is visible in the top right corner, possibly a binding element or a piece of tape. The page is otherwise empty of any text or markings.

Addendum

Addendum Diagnosis

Addendum Diagnosis

Addendum Diagnosis

Source: NCI Genomic Data Commons file be11cbe8-be5f-4633-bd61-fe7ba461cae4 (TCGA-N5-A4RU.D41E40C0-6BC6-4002-956C-924E128161A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).